Somatic mutation profile of tumor specimen 0DI5FM from CCDI case PBBVGC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Dead; Primary diagnosis: Desmoplastic small round cell tumor; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 15.9 years (5,813 days).
Specimen 0DI5FM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a249581-a00e-4829-9ccc-96916ea13765.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DI5EG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1efba986-bf5f-4e9c-9b8a-b326ced0122b

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 3, Intron 2, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS15 | c.1513G>A p.V505M | Missense Mutation (SNP) | VAF 231/568 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.413); catalogued as rs1361620775; called by muse, mutect2, varscan2
- CC2D2A | c.1017C>T p.P339= | Splice Region (SNP) | VAF 56/632 reads (9%) | catalogued as rs777522814; called by muse, mutect2
- CHM | c.1691G>C p.C564S | Missense Mutation (SNP) | VAF 72/1616 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63301872; called by muse, mutect2
- INSYN2B | c.1464A>C p.E488D | Missense Mutation (SNP) | VAF 46/1295 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV56943589; called by muse, mutect2
- MYL7 | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 214/783 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs775993597, COSV56269080; called by muse, mutect2, varscan2
- PHACTR3 | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 36/1148 reads (3%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs1308603666; called by muse, mutect2
- DIAPH2 | c.3004T>G p.F1002V | Missense Mutation (SNP) | VAF 111/1116 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- OMA1 | c.39C>G p.N13K | Missense Mutation (SNP) | VAF 526/1460 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR6Q1 | c.151G>T p.V51L | Missense Mutation (SNP) | VAF 419/961 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- PANX1 | c.690C>A p.Y230* | Nonsense Mutation (SNP) | VAF 396/887 reads (45%) | called by muse, mutect2, varscan2
- CNTNAP3B | c.564A>G p.G188= | Silent (SNP) | VAF 208/1751 reads (12%) | called by muse, mutect2
- ISM1 | c.510G>A p.R170= | Silent (SNP) | VAF 45/350 reads (13%) | called by muse, mutect2, varscan2
- PLXNA3 | c.1170G>C p.V390= | Silent (SNP) | VAF 31/890 reads (3%) | called by muse, mutect2
- CC2D2A | c.2182-15T>C | Intron (SNP) | VAF 424/1004 reads (42%) | called by muse, mutect2
- HBS1L | c.430+2355T>A | Intron (SNP) | VAF 85/1768 reads (5%) | called by muse, mutect2
